Somatic mutation profile of tumor specimen TARGET-40-PAVCHD-01A (aliquot TARGET-40-PAVCHD-01A-01D) from TARGET case TARGET-40-PAVCHD, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.6 years (6,434 days).
Specimen TARGET-40-PAVCHD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 409addcf-b737-4234-9157-7729e4a39d62.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAVCHD-10A (Blood Derived Normal), aliquot TARGET-40-PAVCHD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1afd14ed-8fcc-403b-b61c-238422efefe5

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC16 | c.30742G>A p.E10248K | Missense Mutation (SNP) | VAF 34/572 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV104431823, COSV67455036; called by muse, mutect2
- PCDHB12 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV53399140; called by muse, mutect2, varscan2
- PKHD1L1 | c.7676C>T p.P2559L | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs746424993; called by muse, mutect2, varscan2
- TBC1D8B | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1230350446; called by muse, mutect2, varscan2
- TMC4 | c.898G>A p.D300N (on ENST00000617472 / NM_001145303.3; = p.D294N on NM_144686.4) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs752773628; called by muse, mutect2, varscan2
- MEGF8 | c.3870C>T p.G1290= (on ENST00000251268 / NM_001271938.2; = p.G1223= on NM_001410.3) | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs1568567626; called by muse, mutect2, varscan2
- RECQL4 | c.795C>T p.N265= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs564678543, COSV52879150; called by muse, mutect2
